TCGA case TCGA-AB-2837 — Acute Myeloid Leukemia (TCGA-LAML)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Myeloid Leukemias; Primary site: Hematopoietic and reticuloendothelial systems; Tissue source site: Washington University. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/97007400-de05-402e-8ff7-96893ba02643

Demographics
Sex at birth: female; Race: white; Ethnicity: not hispanic or latino; Age at index: 66 years; Vital status: Dead; Days to death: 0 days.

Diagnoses (1)
1. Acute monocytic leukemia: ICD-O-3 morphology code: 9891/3; ICD-10 code: C93.0; Tissue or organ of origin: Bone marrow; Site of resection or biopsy: Bone marrow; Classification of tumor: primary; Age at diagnosis: 66.8 years (24,381 days); Year of diagnosis: 2002; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: Yes; Calgb risk group: Intermediate/Normal; Fab morphology code: M5.
   Treatment given: Treatment type: Pharmaceutical Therapy, NOS; Therapeutic agents: Hydroxyurea; Treatment dose: 3,000 mg; Timepoint category: Prior to Procurement; Treatment duration: 3.
   Recorded as not given: Pharmaceutical Therapy, NOS (Tretinoin), prior to procurement.

Follow-up (1 entry)
- Follow-up contact recording only the day: day 0.

Molecular and laboratory tests
- CD15 (IHC): Positive.
- CD33 (IHC): Positive.
- FLT3 mutation, nos: Negative.
- IDH1 mutation, nos: Negative; Amino-acid change: R132.
- IDH1 mutation, nos: Negative; Amino-acid change: R140.
- IDH1 mutation, nos: Negative; Amino-acid change: R172.
- MPO (IHC): Negative.
- NPM1 mutation, nos: Positive.
- NSE (IHC): Positive.
- RAS, NOS mutation, nos: Negative.
- Test (Cytogenetics, NOS): Normal.
- Test (IHC): Positive.
- Bone Marrow metamyelocytes 4%.
- Hemoglobin 10 g/dL.
- Bone Marrow blast count 7%.
- Bone Marrow lymphocytes 0%.
- Bone Marrow segmented neutrophil 20%.
- Blast Count 90%.
- Leukocytes 112 ×10³/µL.
- Bone Marrow neutrophil bands 6%.
- Bone Marrow myelocytes 3%.
- Bone Marrow monocytes 0%.
- Metaphase Nucleus Count (Cytogenetics, NOS) 20.
- Bone Marrow prolymphocytes 0%.
- Bone Marrow eosinophil 1%.
- Bone Marrow promyelocytes 6%.
- Cellularity 90%.
- Bone Marrow basophil 1%.
- Platelets 34 x10^6 cells/mcL.
- Bone Marrow promonocytes 0%.
- Bone Marrow abnormal cells 30%.

Biospecimens (6 samples)
- Samples TCGA-AB-2837-03A, TCGA-AB-2837-03B, TCGA-AB-2837-03C (3 with the same recorded description): Sample type: Primary Blood Derived Cancer - Peripheral Blood; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Peripheral Blood NOS.
- Samples TCGA-AB-2837-11A, TCGA-AB-2837-11B, TCGA-AB-2837-11C (3 with the same recorded description): Sample type: Solid Tissue Normal; Tissue type: Normal; Specimen type: Solid Tissue.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Cells used for analysis source: Bone marrow aspirate; History neoadjuvant treatment: Yes; History hematologic disorder: No; Hydroxyurea treatment days: 3; History neoadjuvant hydroxyurea treatment: Yes; Atra prior to procurement: No; Cytogenetics testing performed: Yes; Metaphases count: 20; Fish performed indicator: No; Molecular studies others performed: No.
- Immunophenotype cytochemistry testing results, Immunophenotype cytochemistry testing result values 1: Cyto and immuno test performed: MPX Negative.
- Immunophenotype cytochemistry testing results, Immunophenotype cytochemistry testing result values 2: Cyto and immuno test performed: NSE Positive.
- Immunophenotype cytochemistry testing results, Immunophenotype cytochemistry testing result values 3: Cyto and immuno test performed: TDT Not Tested.
- Immunophenotype cytochemistry testing results, Immunophenotype cytochemistry testing result values 4: Cyto and immuno test performed: CD3 Not Tested.
- Immunophenotype cytochemistry testing results, Immunophenotype cytochemistry testing result values 5: Cyto and immuno test performed: CD5 Not Tested.
- Immunophenotype cytochemistry testing results, Immunophenotype cytochemistry testing result values 6: Cyto and immuno test performed: CD7 Not Tested.
- Immunophenotype cytochemistry testing results, Immunophenotype cytochemistry testing result values 7: Cyto and immuno test performed: CD10 Not Tested.
- Immunophenotype cytochemistry testing results, Immunophenotype cytochemistry testing result values 8: Cyto and immuno test performed: CD14 Not Tested.
- Immunophenotype cytochemistry testing results, Immunophenotype cytochemistry testing result values 9: Cyto and immuno test performed: CD15 Positive.
- Immunophenotype cytochemistry testing results, Immunophenotype cytochemistry testing result values 10: Cyto and immuno test performed: CD19 Not Tested.
- Immunophenotype cytochemistry testing results, Immunophenotype cytochemistry testing result values 11: Cyto and immuno test performed: CD20 Not Tested.
- Immunophenotype cytochemistry testing results, Immunophenotype cytochemistry testing result values 12: Cyto and immuno test performed: CD23 Not Tested.
- Immunophenotype cytochemistry testing results, Immunophenotype cytochemistry testing result values 13: Cyto and immuno test performed: CD25 Not Tested.
- Immunophenotype cytochemistry testing results, Immunophenotype cytochemistry testing result values 14: Cyto and immuno test performed: CD33 Positive.
- Immunophenotype cytochemistry testing results, Immunophenotype cytochemistry testing result values 15: Cyto and immuno test performed: CD34 Not Tested.
- Immunophenotype cytochemistry testing results, Immunophenotype cytochemistry testing result values 16: Cyto and immuno test performed: CD45 Not Tested.
- Immunophenotype cytochemistry testing results, Immunophenotype cytochemistry testing result values 17: Cyto and immuno test performed: CD56 Not Tested.
- Immunophenotype cytochemistry testing results, Immunophenotype cytochemistry testing result values 18: Cyto and immuno test performed: CD 117 Not Tested.
- Immunophenotype cytochemistry testing results, Immunophenotype cytochemistry testing result values 19: Cyto and immuno test performed: HLA-DR Not Tested.
- Immunophenotype cytochemistry testing results, Immunophenotype cytochemistry testing result values 20: Cyto and immuno test performed: Other CD Positive.
- Molecular analysis abnormality testing results, Molecular analysis abnormality testing result values 1: Molecular abnormality results: FLT3 Mutation Negative.
- Molecular analysis abnormality testing results, Molecular analysis abnormality testing result values 2: Molecular abnormality results: IDH1 R132 Negative.
- Molecular analysis abnormality testing results, Molecular analysis abnormality testing result values 3: Molecular abnormality results: IDH1 R140 Negative.
- Molecular analysis abnormality testing results, Molecular analysis abnormality testing result values 4: Molecular abnormality results: IDH1 R172 Negative.
- Molecular analysis abnormality testing results, Molecular analysis abnormality testing result values 5: Molecular abnormality results: Activating RAS Negative.
- Molecular analysis abnormality testing results, Molecular analysis abnormality testing result values 6: Molecular abnormality results: NPMc Positive.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: event (deceased), 0 days.
